Surgical pathology report (de-identified scan), TCGA case TCGA-R8-A73M, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MD Anderson, specimen TCGA-R8-A73M-01A (Primary Tumor).

(168.0cm 69.4kg BSA: 1.8m²)

Accession:
Specimen Date/Time:

ICD-0-3

Oligodendroglioma NOS
9450/3
Site 4 Brain, supratentorial
C-71.0
JW 8/12/13

DIAGNOSIS

- (A, C) LEFT PARIETAL MASS
OLIGODENDROGLIOMA, GRADE II (WHO). (SEE COMMENT)
- (B) TUMOR MARGIN
Brain tissue with foci of infiltrating oligodendroglioma.

COMMENT

This tumor appears as a round neoplastic cells with perinuclear halos and an overall monomorphism. Foci of this neoplasm show areas of increased hypercellularity with identifiable mitosis. In addition, there are areas of somewhat increased vascular activity. These changes do not rise to the level of an anaplastic oligodendroglioma diagnosis, but should be noted in the follow-up plans for this patient. A 1p/19q analysis will be performed.

GROSS DESCRIPTION

- (A) LEFT PARIETAL MASS – Two pieces of red-tan tissue 1.0 cm in greatest dimension. A portion submitted for frozen section and smear in A1, and the remainder in A2.
*FS/DX: INFILTRATING GLIOMA.
- (B) TUMOR MARGIN – Multiple fragments of beige-tan, friable tissue measuring in aggregate, 1.5 x 0.8 x 0.4 cm. Entirely submitted.
- SECTION CODE: B, entire tissue.
- (C) LEFT PARIETAL MASS – Multiple fragments of beige-tan friable tissue measuring in aggregate, 3.0 x 2.0 x 0.8 cm. Entirely submitted in cassettes C1-C4.

CLINICAL HISTORY

None given.

SNOMED CODES

T-A2000, M-94503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

-----END OF REPORT-----

Source: NCI Genomic Data Commons file de631f88-c7c3-4869-a8b3-c75ffcf0aeb2 (TCGA-R8-A73M.4770EEBC-8DD8-431A-B675-4AF05631FCBA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).